TCGA case TCGA-CG-4460 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3c3d4ef0-019a-423e-89b2-4ac5a7b567ab

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 66 years; Vital status: Dead; Days to death: 669 days (1.8 years).

Diagnoses (3)
1. Adenocarcinoma, intestinal type (the primary disease): ICD-O-3 morphology code: 8144/3; ICD-10 code: C16.2; Tissue or organ of origin: Body of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 66.3 years (24,229 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 669 days (1.8 years).
   Pathology details: Lymph nodes positive: 2; Lymph nodes tested: 33.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Cisplatin; Days to treatment start: 61 days; Days to treatment end: 153 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Fluorouracil + Leucovorin Calcium; Days to treatment start: 487 days (1.3 years); Days to treatment end: 608 days (1.7 years); Treatment outcome: Partial Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the ovary (histology not recorded by GDC).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS.
3. Diagnosis record without a diagnosis name: Age at diagnosis: 67.7 years (24,716 days); Days to diagnosis: 487 days (1.3 years); Prior treatment: Yes.

Follow-up (2 entries)
- Day 487 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 669 days (1.8 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CG-4460-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.9; Shortest dimension: 0.5.
  Slide TCGA-CG-4460-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-CG-4460-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 20; Percent necrosis: 10; Percent stromal cells: 10.
- Sample TCGA-CG-4460-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CG-4460-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Cancer procurement city: Hamburg.
- Drug treatment 3: Pharmaceutical therapy drug name: Folinic acid.
- Drug treatment 5: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: Yes; Tumor status: With tumor; Treatment outcome first course: Partial Remission/Response; Treatment outcome at TCGA followup: Partial Remission/Response.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Ovary; Other malignancy histological type: Malignant neoplasm of ovary.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -4322.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy ovarian cancer treated with chemotherapy.
- Prior malignancy: Prior malignancy ovarian cancer treated with chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 669 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 669 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 487 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-CG-4460-01): tumor purity 0.62, ploidy 3.61, whole-genome doublings 1 (call status: snp_call).
